Somatic mutation profile of tumor specimen 0DIOKD from CCDI case PBBUTV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic small round cell tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 23.4 years (8,532 days).
Specimen 0DIOKD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00227601-f92c-448b-897a-6559cb7bc1ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIOJW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/614aadd6-3f52-4585-9e2a-5e7e1e10b50c

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.843C>A p.D281E | Missense Mutation (SNP) | VAF 317/443 reads (72%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1057519984, CM137620, COSV52664212, COSV52688790, COSV52719382, COSV53103731; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ADAMTS8 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs761860316; called by muse, varscan2
- DPP10 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 190/436 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59683831; called by muse, varscan2
- IQCE | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 180/694 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1217722826; called by muse, varscan2
- PPP2R5B | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 152/358 reads (42%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.729); catalogued as rs577391569, COSV51209778; called by muse, varscan2
- SLC5A12 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 312/836 reads (37%) | catalogued as rs748588404; called by muse, varscan2
- YBX3 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 180/500 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs753555662, COSV54385294; called by muse, varscan2
- CPO | c.760A>C p.S254R | Missense Mutation (SNP) | VAF 154/470 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, varscan2
- ENPP6 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 78/446 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.26); called by muse, varscan2
- FAM83B | c.1774G>C p.D592H | Missense Mutation (SNP) | VAF 180/500 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, varscan2
- KRT33A | c.1169G>A p.C390Y | Missense Mutation (SNP) | VAF 435/1040 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, varscan2
- MYT1L | c.1769G>A p.C590Y | Missense Mutation (SNP) | VAF 184/472 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.771); called by muse, varscan2
- NHLRC1 | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, varscan2
- UMODL1 | c.1137C>G p.S379R | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, varscan2
- CHST2 | c.1335G>C p.L445= | Silent (SNP) | VAF 252/654 reads (39%) | called by muse, varscan2
- CROCC2 | c.471G>C p.L157= | Silent (SNP) | VAF 148/340 reads (44%) | called by muse, varscan2
- FAM222A | c.387C>T p.A129= | Silent (SNP) | VAF 102/232 reads (44%) | catalogued as rs780835586, COSV62723449; called by muse, varscan2
- NLRP10 | c.447T>C p.S149= | Silent (SNP) | VAF 133/307 reads (43%) | catalogued as COSV60780479; called by muse, varscan2
- OR8K3 | c.639A>T p.I213= | Silent (SNP) | VAF 349/775 reads (45%) | catalogued as COSV57131913; called by muse, varscan2
- PCDH8 | c.2610G>T p.R870= | Silent (SNP) | VAF 73/243 reads (30%) | called by muse, varscan2
- PGK1 | c.249A>G p.V83= | Silent (SNP) | VAF 376/430 reads (87%) | called by muse, varscan2
- MUC2 | chr11:1095502 C>G | 3'Flank (SNP) | VAF 194/478 reads (41%) | catalogued as rs1318993001; called by muse, varscan2
